Somatic mutation profile of tumor specimen TCGA-VD-A8KE-01A (aliquot TCGA-VD-A8KE-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KE, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,290 days).
Specimen TCGA-VD-A8KE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fadba69a-e5d7-4501-ac69-de7be7c3cb73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KE-10A (Blood Derived Normal), aliquot TCGA-VD-A8KE-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40d287f2-605f-45b5-b61e-6af0c697a9e4

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 59/68 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV63309272; called by muse, mutect2, varscan2
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 88/138 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C14orf39 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1171467636, COSV58781469; called by muse, mutect2
- CLDN2 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194923745, COSV100390096; called by muse, mutect2
- KCNU1 | c.1241T>C p.I414T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs1363114837; called by muse, mutect2
- TECTA | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50757519; called by muse, mutect2
- COG1 | c.729C>G p.N243K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CPEB3 | c.1688T>C p.V563A | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- F12 | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- QKI | c.402+2T>A p.X134_splice | Splice Site (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- TPPP2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TTN | c.61522T>G p.Y20508D (on ENST00000591111; = p.Y13084D on NM_003319.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | PolyPhen possibly damaging (0.656); called by muse, varscan2
- VAV3 | c.2395T>A p.F799I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACOX1 | c.1941C>T p.H647= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs768307965; called by muse, mutect2, varscan2
- CR1L | c.111C>T p.V37= | Silent (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- CWC25 | c.381T>A p.L127= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- EFHC1 | c.837C>T p.H279= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs752122624; called by muse, mutect2, varscan2
- LIFR | c.1719A>G p.V573= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs183990367, COSV54699447; called by muse, mutect2, varscan2
- MYF6 | c.102T>C p.Y34= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as rs1035874570; called by muse, mutect2
- PCDH10 | c.2871T>C p.S957= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs937490253, COSV52090649; called by muse, mutect2, varscan2
- RAB20 | c.430A>C p.R144= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
